Somatic mutation profile of tumor specimen TCGA-KN-8422-01A (aliquot TCGA-KN-8422-01A-11D-2310-10) from TCGA case TCGA-KN-8422, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 28.2 years (10,303 days).
Specimen TCGA-KN-8422-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 684c6cef-17c8-4b22-859d-cc9e66a4f81e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8422-11A (Solid Tissue Normal), aliquot TCGA-KN-8422-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c41fe2ba-aec1-49e0-892e-f7121a41bac6

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BHLHE40 | c.1136A>C p.Q379P | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV99847997; called by muse, mutect2, varscan2
- C3orf38 | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV59628340; called by muse, mutect2
- COL28A1 | c.1762A>G p.T588A | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV101258412; called by muse, mutect2
- KMT2D | c.8890G>T p.V2964F | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as COSV56458697; called by muse, mutect2, varscan2
- MARCO | c.1294del p.R432Efs*114 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | catalogued as COSV59052349; called by mutect2, pindel, varscan2
- MAST1 | c.4492C>A p.P1498T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs779152408; called by mutect2, varscan2
- NLRP7 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV100051922; called by muse, mutect2, varscan2
- SIGLEC14 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.587); catalogued as rs753560578, COSV55777551, COSV55779228; called by muse, mutect2, varscan2
- ACBD3 | c.703_705dup p.E235dup | In Frame Ins (INS) | VAF 20/76 reads (26%) | called by mutect2, varscan2
- CPT2 | c.1011C>G p.H337Q | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- MPHOSPH8 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- NDST4 | c.2069T>A p.I690N | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR10Z1 | c.164T>A p.L55Q | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF528 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEP164 | c.147G>T p.L49= | Silent (SNP) | VAF 57/127 reads (45%) | called by muse, mutect2, varscan2
- CLASP2 | c.3297C>T p.H1099= (on ENST00000359576; = p.H1098= on NM_015097.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 31/113 reads (27%) | called by muse, mutect2, varscan2
